Gene-level copy-number profile of tumor specimen TCGA-DY-A1DC-01A from TCGA case TCGA-DY-A1DC, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIA; Age at diagnosis: 72.4 years (26,436 days).
Specimen TCGA-DY-A1DC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.6f97bade-3e85-47cb-9bb7-868f72aaf530.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DY-A1DC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e357eb03-ecf9-4755-a9f9-6646392af2b4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,698; copy number 2: 41,051; copy number 3: 3,357; copy number 4: 5,708; copy number 6: 3; copy number 7: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DY-A1DC-01A-31D-A151-01): tumor purity 0.71, ploidy 2.21, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:195,003,711–195,026,370, 1 gene, copy number 6 (within-gene range 2–6): AC010983.1.
- chr6:46,129,989–46,146,688, 1 gene, copy number 7: ENPP4.
- chr7:25,948,657–25,949,986, 2 genes, copy number 6: AC010719.1, MIR148A.

Autosomal genes at a single copy (total copy number 1): 7,277. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
